TCGA case TCGA-XF-AAMF — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: University of Southern California. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/93fbe302-a2e0-4cf4-a638-312786f547c2

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 68 years; Vital status: Dead; Days to death: 329 days.

Diagnoses (6)
1. Transitional cell carcinoma (the primary disease): ICD-O-3 morphology code: 8120/3; ICD-10 code: C67.9; Tissue or organ of origin: Bladder, NOS; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 68.5 years (25,023 days); Year of diagnosis: 2004; Method of diagnosis: Surgical Resection; AJCC staging edition: 6th; AJCC pathologic T: T4; AJCC pathologic N: N2; AJCC pathologic M: MX; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Prior malignancy: no; Synchronous malignancy: Yes; Prior treatment: No; Sites of involvement: Lymph node, NOS.
   Pathology details: Consistent pathology review: Yes; Extracapsular extension present: No; Lymph nodes positive: 5; Lymph nodes tested: 83; Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Gemcitabine; Days to treatment start: 161 days; Days to treatment end: 274 days; Treatment outcome: Progressive Disease.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Carcinoma, NOS: Tissue or organ of origin: Prostate gland; Classification of tumor: Synchronous primary; AJCC pathologic T: T2a.
3. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Prostate gland; Laterality: Left; Classification of tumor: Synchronous primary; Age at diagnosis: 68.6 years (25,039 days); Days to diagnosis: 16 days; AJCC staging edition: 6th; AJCC pathologic T: T2a; AJCC pathologic N: NX; AJCC pathologic M: MX.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 16 days; Treatment anatomic sites: Prostate.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
4. Metastasis of diagnosis 1 (Transitional cell carcinoma), site: Lung, NOS. Age at diagnosis: 68.9 years (25,180 days); Days to diagnosis: 157 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
5. Metastasis of diagnosis 1 (Transitional cell carcinoma), site: Bone, NOS. Age at diagnosis: 68.9 years (25,180 days); Days to diagnosis: 157 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
6. Metastasis of diagnosis 1 (Transitional cell carcinoma), site: Lymph node, NOS. Age at diagnosis: 68.9 years (25,180 days); Days to diagnosis: 157 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (5 entries)
- Day 157 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 157 days.
- Day 157 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 157 days.
- Day 157 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 157 days.
- Days to follow up: 329 days; Disease response: With Tumor.
- Karnofsky performance status: 90.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 93 kg; Height: 178 cm; BMI: 29.4.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 32; Tobacco smoking quit year: 1974; Age at onset: 23.
- Occupation duration years: 35; Occupation type: Sales, Marketing and Public Relations Professionals.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Lung Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-XF-AAMF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 830 mg.
  Slide TCGA-XF-AAMF-01A-02-TSB: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 40; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-XF-AAMF-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-XF-AAMF-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Occupation current: business owner; Occupation primary: Sales; Occupation primary industry: Retail, Construction Supplies; Tobacco smoking history indicator: 3; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Non-Papillary; Anatomic organ subdivision: Bladder - NOS; Method initial path diagnosis: Transurethral resection (TURBT); Lymph nodes examined: Yes; Lymphovascular invasion: Yes; Incidental prostate cancer indicator: Yes; AJCC path pathologic T incidental prostate: pT2a; Treatment outcome first course: Stable Disease.
- Stage record, Gleason grading: Gleason score: 6.
- Metastatic site list: Metastasis site: Lymph node only.
- History non muscle invasive blca: Noninvasive bladder history: No.
- Drug treatment 1: Treatment best response: Clinical Progressive Disease.
- Other malignancy form: Malignancy type: Synchronous Malignancy; Other malignancy anatomic site: Prostate; Other malignancy histological type: Adenocarcinoma, Not Otherwise Specified.
- Other malignancy form, Surgery: Other malignancy surgery type: Prostatectomy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 329 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 329 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 157 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-XF-AAMF-01A-21D-A42D-01): tumor purity 0.72, ploidy 1.96, whole-genome doublings 0.
